Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96M, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96M-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

ICD O-3
Thymoma, type AB
malignant 8582/3
Site Anterior mediastinum
C38.1
JAS 4/7/14

Pathology Report-Summary:

Material:

Tumor: 13.0 x 11.0 x 7.0 cm

Diagnosis:

Type A/B-Thymoma

pT1b, pNx

Masaoka: II.2

Immunohistochemistry

epithelial cells positive for: CK5/6
strong membrane staining for EGFR

epithelial cells negative for: CD5, CD117

CD5-, CD1a-positive immature T-lymphocytes

Source: NCI Genomic Data Commons file e4458e3f-1336-44ad-995e-b049b5bea996 (TCGA-ZB-A96M.B6168DA9-5373-45ED-9EE6-A26D819D9F5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).